Somatic mutation profile of cancer-model specimen HCM-BROD-0482-C34-85M (3D Organoid, passage 11; aliquot HCM-BROD-0482-C34-85M-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0482-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 54.5 years (19,904 days).
Specimen HCM-BROD-0482-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da503c20-7f66-4162-9ebb-39b3d4fe7848.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0482-C34-10A (Blood Derived Normal), aliquot HCM-BROD-0482-C34-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1c352fe-89cc-4aa1-84e8-9b270f6d2c0a

The open-access MAF lists 148 somatic variants for this specimen: 104 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 39, Nonsense Mutation 6, Intron 2, Frame Shift Del 2, 3'Flank 1, 5'Flank 1, In Frame Del 1, 5'UTR 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 75/75 reads (100%) | catalogued as rs1131690915, CM0910363, COSV57299384, COSV99927549; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 251/252 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD16B | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 385/1736 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as rs761871122; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1654G>A p.G552R | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746126694, COSV55007123; called by muse, mutect2, varscan2
- ADGRG1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs770060105, COSV101113364; called by muse, mutect2, varscan2
- ADRM1 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 354/1448 reads (24%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.556); catalogued as rs758918944; called by muse, varscan2
- ASIC2 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as COSV56757939, COSV99861304; called by muse, mutect2, varscan2
- CCDC197 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as rs770665618, COSV58939428; called by muse, mutect2, varscan2
- CD163L1 | c.1707G>T p.E569D | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58011714; called by muse, mutect2, varscan2
- CHPF | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 120/444 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.201); catalogued as COSV99704708; called by muse, varscan2
- CLDN14 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 74/804 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as rs1041031415; called by muse, mutect2
- CPA3 | c.539G>A p.W180* | Nonsense Mutation (SNP) | VAF 105/170 reads (62%) | catalogued as COSV56045388, COSV99936025; called by muse, mutect2, varscan2
- DSCAM | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 95/783 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.098); catalogued as COSV68643594; called by muse, mutect2, varscan2
- ERAP2 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as rs1489043420; called by muse, mutect2
- ERBB3 | c.1742A>T p.D581V | Missense Mutation (SNP) | VAF 224/226 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57254269; called by mutect2, varscan2
- ERCC4 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 120/201 reads (60%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs747564755, COSV61314159; called by muse, mutect2, varscan2
- FBN2 | c.7140C>A p.D2380E | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52499446; called by muse, mutect2, varscan2
- GDF6 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs778557602; called by muse, mutect2, varscan2
- GLIPR1 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as rs773209636, COSV56990866; called by muse, mutect2, varscan2
- JOSD2 | c.379G>C p.V127L | Missense Mutation (SNP) | VAF 74/611 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV101209131; called by muse, mutect2, varscan2
- KCNH4 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 75/378 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1057461290, COSV52916572; called by muse, mutect2, varscan2
- KIF25 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs147788292; called by muse, mutect2, varscan2
- LDLRAD3 | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 65/318 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59690434; called by muse, mutect2, varscan2
- LMAN1 | c.543C>A p.D181E | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51826477, COSV51829672; called by muse, mutect2, varscan2
- LONP2 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 157/411 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.195); catalogued as rs774169335; called by muse, mutect2, varscan2
- LRRTM4 | c.679C>A p.R227S | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101297775, COSV69143045; called by muse, mutect2, varscan2
- NPIPB15 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 198/436 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs761279319; called by muse, mutect2, varscan2
- OLFML2B | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 85/410 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs575795425, COSV54196325, COSV54196652; called by muse, mutect2, varscan2
- OR1E2 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV50265794; called by muse, mutect2, varscan2
- OXR1 | c.1504G>T p.E502* (on ENST00000442977 / NM_001198532.1; = p.E501* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 128/249 reads (51%) | catalogued as COSV56324972; called by muse, mutect2, varscan2
- PPP1R3A | c.2974T>C p.C992R | Missense Mutation (SNP) | VAF 61/458 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.091); catalogued as rs1321061763; called by muse, mutect2, varscan2
- PRR12 | c.1882G>A p.E628K (on ENST00000615927; = p.E1449K on NM_020719.3) | Missense Mutation (SNP) | VAF 47/325 reads (14%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs747927122; called by muse, mutect2, varscan2
- PTPRB | c.2482C>T p.R828C | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.717); catalogued as rs746899191, COSV54240278; called by muse, mutect2, varscan2
- RP1 | c.1535C>A p.S512Y | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55117841; called by mutect2, varscan2
- SALL4 | c.1871C>T p.T624M | Missense Mutation (SNP) | VAF 281/422 reads (67%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs146604877, COSV53852490; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- SUPT3H | c.621A>T p.K207N (on ENST00000371460 / NM_181356.3; = p.K196N on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60933976; called by muse, mutect2
- SYNE2 | c.16653G>C p.L5551F | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59943643; called by muse, mutect2, varscan2
- TBX18 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 89/299 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs917227168, COSV63735941; called by muse, mutect2, varscan2
- TCHH | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 98/592 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as rs769313231; called by muse, mutect2, varscan2
- TGM4 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs756015035; called by muse, mutect2, varscan2
- ZNF506 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV101475598; called by muse, mutect2, varscan2
- ADCY4 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFG1L | c.830T>A p.L277Q | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKK1 | c.2274G>T p.K758N | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); called by mutect2, varscan2
- AP2A1 | c.2839C>G p.P947A | Missense Mutation (SNP) | VAF 109/363 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- APOL2 | c.138G>A p.R46= | Splice Region (SNP) | VAF 45/68 reads (66%) | called by muse, mutect2, varscan2
- ARFGEF1 | c.3430G>T p.V1144F | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATG2B | c.2200C>T p.H734Y | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- BAHCC1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 163/367 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- CABLES2 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 239/964 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- CABS1 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.028); called by muse, mutect2
- CCL15 | c.97A>G p.M33V | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT tolerated (0.84); PolyPhen benign (0.02); called by muse, mutect2
- CD4 | c.665_667del p.S222del | In Frame Del (DEL) | VAF 31/239 reads (13%) | called by mutect2, pindel, varscan2
- CFAP92 | c.2873C>T p.S958F | Missense Mutation (SNP) | VAF 148/213 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COQ6 | c.1210_1210+3del p.X404_splice | Splice Site (DEL) | VAF 42/112 reads (38%) | called by mutect2, pindel, varscan2
- CSRNP3 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 126/293 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DNAH9 | c.2689C>G p.L897V | Missense Mutation (SNP) | VAF 51/348 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EDDM3B | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 100/273 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FYN | c.1217T>G p.I406S | Missense Mutation (SNP) | VAF 140/232 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GABRQ | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 137/517 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIN2B | c.4059G>C p.K1353N | Missense Mutation (SNP) | VAF 43/322 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HLA-DQA2 | c.359A>T p.K120M | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHA1 | c.721G>C p.A241P | Missense Mutation (SNP) | VAF 142/558 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2
- KIF27 | c.1475A>G p.D492G | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- KIR2DL4 | c.436G>C p.E146Q (on ENST00000396284; = p.E107Q on NM_001080770.2) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KRT72 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMB3 | c.518G>A p.C173Y | Missense Mutation (SNP) | VAF 151/435 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP4 | c.4045G>T p.D1349Y | Missense Mutation (SNP) | VAF 129/322 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- LUC7L3 | c.466C>A p.Q156K | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- LY86 | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCPH1 | c.2225G>A p.S742N | Missense Mutation (SNP) | VAF 132/134 reads (99%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC22 | c.2285G>T p.G762V | Missense Mutation (SNP) | VAF 24/564 reads (4%) | SIFT deleterious (0.04); called by muse, mutect2
- MYBPC2 | c.3218G>C p.G1073A | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- NBPF10 | c.10660G>T p.E3554* | Nonsense Mutation (SNP) | VAF 35/251 reads (14%) | called by muse, mutect2, varscan2
- NEO1 | c.946G>C p.G316R | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NFATC3 | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 163/448 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NISCH | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 102/151 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NLGN4X | c.2302C>A p.P768T | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NTSR1 | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 80/1634 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- OLFML2A | c.1545G>A p.W515* | Nonsense Mutation (SNP) | VAF 159/339 reads (47%) | called by muse, mutect2, varscan2
- OR5G3 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 111/256 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PADI1 | c.1749C>G p.F583L | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLCH1 | c.675T>A p.S225R (on ENST00000340059 / NM_001130960.2; = p.S237R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLTP | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.133); called by muse, varscan2
- POGLUT2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 130/250 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POGLUT3 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PSMC2 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 34/507 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); called by muse, mutect2
- SGCD | c.40C>T p.P14S (on ENST00000435422 / NM_001128209.2; = p.P15S on NM_000337.5) | Missense Mutation (SNP) | VAF 172/266 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- SLC9A9 | c.1278G>C p.K426N | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- STKLD1 | c.1148_1149del p.L383Rfs*160 | Frame Shift Del (DEL) | VAF 70/335 reads (21%) | called by mutect2, pindel, varscan2
- STYXL2 | c.2378C>T p.S793F | Missense Mutation (SNP) | VAF 149/400 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- TMEM132C | c.2203C>A p.L735M | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- TRBV19 | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 79/388 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- TRBV19 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 61/434 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TRIP6 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 111/670 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ULK4 | c.1559T>G p.I520R | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- WDR11 | c.2342A>T p.E781V | Missense Mutation (SNP) | VAF 72/88 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ZNF234 | c.1278A>C p.K426N | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ZNF248 | c.844A>G p.N282D | Missense Mutation (SNP) | VAF 106/385 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF417 | c.1252A>T p.R418W | Missense Mutation (SNP) | VAF 183/583 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ZNF569 | c.272A>T p.N91I | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- ZNF7 | c.104del p.E35Gfs*9 | Frame Shift Del (DEL) | VAF 71/292 reads (24%) | called by mutect2, pindel, varscan2
- ZNF843 | c.737G>C p.G246A | Missense Mutation (SNP) | VAF 89/310 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ZNF91 | c.601A>T p.K201* | Nonsense Mutation (SNP) | VAF 55/354 reads (16%) | called by muse, mutect2, varscan2
- AASDH | c.966T>C p.F322= | Silent (SNP) | VAF 115/264 reads (44%) | called by muse, mutect2, varscan2
- ADAM30 | c.2331T>C p.S777= | Silent (SNP) | VAF 16/454 reads (4%) | called by muse, mutect2
- ADAMTSL1 | c.1956C>A p.R652= | Silent (SNP) | VAF 59/482 reads (12%) | catalogued as COSV52816509; called by muse, mutect2, varscan2
- B4GALNT4 | c.936G>A p.E312= | Silent (SNP) | VAF 36/416 reads (9%) | called by muse, mutect2
- BRINP1 | c.2085C>G p.L695= | Silent (SNP) | VAF 171/347 reads (49%) | called by muse, mutect2, varscan2
- BUB1 | c.1038G>A p.Q346= | Silent (SNP) | VAF 75/251 reads (30%) | called by muse, mutect2, varscan2
- CACNA1I | c.1629C>T p.P543= | Silent (SNP) | VAF 194/442 reads (44%) | catalogued as rs534441146, COSV60803033; called by muse, mutect2, varscan2
- CDK17 | c.1182G>A p.V394= | Silent (SNP) | VAF 37/164 reads (23%) | called by muse, mutect2, varscan2
- ELMO2 | c.714G>A p.L238= | Silent (SNP) | VAF 119/429 reads (28%) | catalogued as COSV51683628; called by muse, mutect2, varscan2
- ELOA2 | c.609C>T p.G203= | Silent (SNP) | VAF 12/296 reads (4%) | catalogued as rs1240548288; called by muse, mutect2
- FAM185A | c.315G>A p.V105= | Silent (SNP) | VAF 72/492 reads (15%) | called by muse, mutect2, varscan2
- FOXD4L1 | c.658C>T p.L220= | Silent (SNP) | VAF 138/485 reads (28%) | catalogued as rs760574270; called by muse, varscan2
- GOLGA2 | c.2313C>G p.A771= | Silent (SNP) | VAF 24/493 reads (5%) | called by muse, mutect2
- HELZ2 | c.7530G>A p.G2510= (on ENST00000467148 / NM_001037335.2; = p.G1941= on NM_033405.3) | Silent (SNP) | VAF 84/1360 reads (6%) | called by muse, mutect2
- KCNB2 | c.1446C>T p.A482= | Silent (SNP) | VAF 62/275 reads (23%) | catalogued as rs537263702, COSV73049321; called by muse, mutect2, varscan2
- LILRB1 | c.312C>A p.P104= (on ENST00000427581; = p.P68= on NM_006669.6) | Silent (SNP) | VAF 237/559 reads (42%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1551T>C p.P517= | Silent (SNP) | VAF 16/234 reads (7%) | catalogued as COSV53577581; called by muse, mutect2
- MAP2K1 | c.396G>T p.A132= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as rs139364105, COSV61073184; called by muse, mutect2, varscan2
- MIER2 | c.1059C>T p.F353= | Silent (SNP) | VAF 165/459 reads (36%) | catalogued as rs369643922; called by muse, mutect2, varscan2
- MLH3 | c.3801G>A p.V1267= (on ENST00000355774 / NM_001040108.2; = p.V1243= on NM_014381.3) | Silent (SNP) | VAF 36/187 reads (19%) | called by muse, mutect2, varscan2
- MRPL14 | c.255C>A p.L85= | Silent (SNP) | VAF 112/464 reads (24%) | catalogued as COSV64394640; called by muse, mutect2
- MYH3 | c.450G>A p.E150= | Silent (SNP) | VAF 220/305 reads (72%) | called by muse, mutect2, varscan2
- MYO7B | c.3381G>T p.L1127= | Silent (SNP) | VAF 19/188 reads (10%) | called by muse, mutect2, varscan2
- OBSCN | c.15384C>T p.F5128= | Silent (SNP) | VAF 44/238 reads (18%) | catalogued as rs1458344005; called by muse, mutect2, varscan2
- OR9Q1 | c.210C>T p.D70= | Silent (SNP) | VAF 373/375 reads (99%) | catalogued as rs753329362, COSV59038570; called by muse, mutect2, varscan2
- PKHD1 | c.687C>T p.F229= | Silent (SNP) | VAF 51/287 reads (18%) | called by muse, mutect2, varscan2
- POSTN | c.786C>A p.A262= | Silent (SNP) | VAF 135/137 reads (99%) | catalogued as rs1199086936, COSV65714624; called by muse, mutect2, varscan2
- PPFIA3 | c.2115G>A p.G705= | Silent (SNP) | VAF 78/519 reads (15%) | called by muse, mutect2, varscan2
- PRDM15 | c.528C>T p.N176= | Silent (SNP) | VAF 143/727 reads (20%) | catalogued as rs755076338, COSV54151767; called by muse, mutect2, varscan2
- RIMBP2 | c.3126A>G p.A1042= | Silent (SNP) | VAF 41/134 reads (31%) | called by muse, mutect2, varscan2
- RNF145 | c.399G>A p.V133= (on ENST00000424310 / NM_001199383.2; = p.V161= on NM_144726.2) | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs1029483239; called by muse, mutect2, varscan2
- RTF2 | c.861C>T p.S287= | Silent (SNP) | VAF 78/490 reads (16%) | catalogued as rs767259244, COSV50130571; called by muse, mutect2, varscan2
- STX11 | c.156G>A p.Q52= | Silent (SNP) | VAF 87/248 reads (35%) | catalogued as rs777737910; called by muse, mutect2, varscan2
- TSPAN9 | c.492G>A p.T164= | Silent (SNP) | VAF 143/330 reads (43%) | catalogued as rs1004762961; called by muse, mutect2, varscan2
- UGT1A8 | c.150C>T p.L50= | Silent (SNP) | VAF 82/303 reads (27%) | called by muse, mutect2, varscan2
- URB1 | c.3840A>G p.T1280= | Silent (SNP) | VAF 54/512 reads (11%) | catalogued as rs1190596413; called by muse, mutect2
- VPS13C | c.4344T>G p.P1448= (on ENST00000644861 / NM_020821.3; = p.P1405= on NM_017684.5) | Silent (SNP) | VAF 58/198 reads (29%) | called by muse, mutect2, varscan2
- ZMYM1 | c.1428C>T p.F476= | Silent (SNP) | VAF 105/277 reads (38%) | called by muse, mutect2, varscan2
- ZNF223 | c.726A>G p.R242= | Silent (SNP) | VAF 45/327 reads (14%) | called by muse, mutect2, varscan2
- DYRK4 | chr12:4588962 T>C | 5'Flank (SNP) | VAF 67/293 reads (23%) | called by muse, mutect2, varscan2
- FRMPD2 | chr10:48156234 G>A | 3'Flank (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-7630G>A | Intron (SNP) | VAF 147/356 reads (41%) | called by muse, mutect2, varscan2
- MDM2 | c.-210G>A | 5'UTR (SNP) | VAF 55/264 reads (21%) | catalogued as COSV99254910; called by muse, mutect2, varscan2
- PTTG1IP | c.169-506G>T | Intron (SNP) | VAF 67/592 reads (11%) | called by muse, mutect2, varscan2
